Gene-level copy-number profile of tumor specimen TCGA-02-0079-01A from TCGA case TCGA-02-0079, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.0 years (21,173 days).
Specimen TCGA-02-0079-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.0fa9e5b8-3b0a-4e23-81ef-edd61b51dc01.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-02-0079-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a7a510b8-eab9-4bd5-8cb1-5bc924a407d7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 55; copy number 1: 14,907; copy number 2: 37,564; copy number 3: 7,211; copy number 7: 4; copy number 9: 25; copy number 10: 14; copy number 11: 13; copy number 12: 26; copy number 13: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-02-0079-01): tumor purity 0.51, ploidy 1.86, whole-genome doublings 0 (call status: snp_call).

Homozygous deletions (total copy number 0; autosomes only): 55 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:59,459,072–59,465,682, 1 gene: AC016229.1.
- chr18:59,685,820–62,980,433, 54 genes: AC010776.1, AC010776.2, AC010776.3, RPS26P54, GLUD1P4, AC098847.1, PMAIP1, AC107990.1, NFE2L3P1, RN7SL342P, ENTR1P1, AC090377.1, SINHCAFP2, RNU6-567P, AC090771.2, RPS3AP49, RNU4-17P, AC090771.1, AC090621.1, AC091576.1, MC4R, AC010928.2, MRPS5P4, AC010928.3, AC010928.1, AC113137.1, CTBP2P3, HMGN1P31, CDH20, RNU6-116P, RPL30P14, AC090409.2, AC090409.1, AC105094.2, AC105094.1, LINC01544, RNF152, PIGN, RPIAP1, RELCH, AC027514.1, AC027514.2, TNFRSF11A, Y_RNA, AC100843.1, RPL17P44, AC100843.2, ACTBP9, ZCCHC2, AC064801.1, AC064801.2, RN7SL705P, PHLPP1, RNU6-142P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 83 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:53,265,461–54,740,715, 25 genes, copy number 9 (within-gene range 1–9): RNU6-310P, FIP1L1, AC058822.1, LNX1, LNX1-AS1, AC095040.1, LNX1-AS2, AC124017.1, AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT.
- chr4:63,465,511–63,529,761, 1 gene, copy number 13: AC093730.1.
- chr4:66,169,778–66,329,377, 2 genes, copy number 12 (within-gene range 1–12): AC110809.1, MIR1269A.
- chr4:94,675,245–95,549,206, 4 genes, copy number 7 (within-gene range 1–7): AC108067.1, BMPR1B-DT, BMPR1B, UNC5C.
- chr4:97,120,701–97,135,059, 1 gene, copy number 11: AC108515.1.
- chr4:106,921,802–107,283,806, 2 genes, copy number 12 (within-gene range 1–12): DKK2, RAC1P5.
- chr4:107,590,276–108,419,763, 12 genes, copy number 11: PAPSS1, SGMS2, CYP2U1-AS1, RNU6-733P, CYP2U1, AC096564.1, HADH, LEF1, LEF1-AS1, RPSAP34, ZACNP1, EXOC7P1.
- chr4:112,513,516–112,798,691, 19 genes, copy number 12: NEUROG2, NEUROG2-AS1, RPL23AP94, ZGRF1, H3P14, LARP7, MIR302CHG, MIR367, MIR302D, MIR302A, MIR302C, MIR302B, OSTCP4, AC106864.1, WRBP1, AC017007.3, Y_RNA, RPL7AP30, AC017007.4.
- chr4:112,826,307–112,882,330, 3 genes, copy number 12: AC017007.2, AC017007.5, AC017007.1.
- chr4:118,033,618–118,715,433, 14 genes, copy number 10 (within-gene range 1–10): NDST3, FKBP4P1, SNHG8, SNORA24, PRSS12, NDUFS5P5, AC092670.1, CEP170P1, AC110079.1, RNU6-1054P, CICP16, SEPTIN14P4, METTL14-DT, METTL14.

Autosomal genes at a single copy (total copy number 1): 12,492. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
